Somatic mutation profile of tumor specimen 0DHE06 from CCDI case PBBUET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.7 years (4,623 days).
Specimen 0DHE06: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 890b2014-420f-4b49-9d69-6027b93335cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/773e8c58-3fb4-4300-a532-1c38a2bc0d4c

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 373/768 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 424/927 reads (46%) | catalogued as rs779070661, CM1414538, COSV59954404; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 273/648 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs759429383, COSV64239223; called by muse, varscan2
- GALNT8 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 286/642 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs181113647; called by muse, mutect2, varscan2
- IFNL1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 74/1124 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs369965543, COSV100373654; called by muse, mutect2
- NTSR2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 419/854 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs534548253, COSV60993363; called by muse, mutect2, varscan2
- ARID1B | c.6667dup p.A2223Gfs*6 | Frame Shift Ins (INS) | VAF 244/367 reads (66%) | called by mutect2, pindel, varscan2
- BAZ2B | c.4541C>G p.T1514R | Missense Mutation (SNP) | VAF 429/843 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- BICRA | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 361/555 reads (65%) | called by muse, mutect2, varscan2
- C9orf85 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 250/528 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DDX3X | c.817C>A p.P273T (on ENST00000399959; = p.P274T on NM_001356.5) | Missense Mutation (SNP) | VAF 351/370 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENKD1 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 371/856 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RND1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 390/901 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZC3H6 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 219/506 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by mutect2, varscan2
- MYH9 | c.5694C>T p.R1898= | Silent (SNP) | VAF 338/721 reads (47%) | catalogued as rs559732738, COSV53385228; called by muse, mutect2, varscan2
- PCDHB3 | c.1314C>G p.T438= | Silent (SNP) | VAF 384/856 reads (45%) | catalogued as rs1554272419; called by muse, mutect2, varscan2
- RRS1 | c.366C>T p.G122= | Silent (SNP) | VAF 185/390 reads (47%) | called by muse, mutect2, varscan2
- TMEM151B | c.1683C>T p.C561= | Silent (SNP) | VAF 240/274 reads (88%) | catalogued as rs1406018654; called by muse, mutect2, varscan2
